Somatic mutation profile of tumor specimen TCGA-12-3644-01A (aliquot TCGA-12-3644-01A-01W-0922-08) from TCGA case TCGA-12-3644, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.8 years (17,468 days).
Specimen TCGA-12-3644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abcd9ae-f22d-4af1-829c-9193cb2ce9ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3644-10A (Blood Derived Normal), aliquot TCGA-12-3644-10A-01W-0922-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574b1c64-de0a-43f8-82fa-50722ef99c7e

The open-access MAF lists 97 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 64, Silent 25, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.740T>G p.L247* | Nonsense Mutation (SNP) | VAF 119/169 reads (70%) | hotspot (GDC flag); catalogued as rs1057519368, COSV64289211, COSV64294730, COSV64302434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2489+1G>A p.X830_splice | Splice Site (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); catalogued as rs764754259, CS030560, CS030561, CS133197, COSV57295644, COSV57300119, COSV57302985; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 413/482 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.2342C>T p.T781I | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99651395; called by muse, mutect2
- ADGRA2 | c.2474dup p.I826Hfs*37 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | catalogued as rs775086506; called by pindel, varscan2
- ADGRV1 | c.13315C>G p.Q4439E | Missense Mutation (SNP) | VAF 33/667 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV101315671; called by muse, mutect2
- APEH | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99610629; called by muse, mutect2
- ARSF | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs369509309, COSV100839457; called by muse, mutect2, varscan2
- ASXL1 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038251; called by muse, mutect2, varscan2
- BDKRB2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs201166893; called by muse, mutect2, varscan2
- BOD1L1 | c.7502C>T p.S2501L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99238857; called by muse, mutect2
- BPIFB6 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs371787213; called by muse, mutect2, varscan2
- C2orf42 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100033770; called by muse, mutect2
- CDH10 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV100050657; called by muse, mutect2, varscan2
- CHST1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.837); catalogued as COSV100346110; called by muse, mutect2, varscan2
- COL11A1 | c.4357G>A p.G1453R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100615656; called by mutect2, varscan2
- CYTH1 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as COSV100739217; called by muse, mutect2
- DBH | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV55039782, COSV99707973; called by muse, mutect2, varscan2
- DCAF17 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100266033, COSV100266052; called by muse, mutect2
- DHX16 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 42/360 reads (12%) | catalogued as COSV100905158; called by muse, mutect2, varscan2
- EMILIN2 | c.2204G>A p.S735N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99598307; called by muse, mutect2, varscan2
- FADS6 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1247592363, COSV100044033; called by muse, mutect2, varscan2
- FBXO22 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 31/594 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV99143212; called by muse, mutect2
- FOLH1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs757958518, COSV57054870; called by muse, mutect2, varscan2
- GGT5 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs749024136, COSV54072477; called by muse, varscan2
- HDX | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99946926; called by muse, mutect2, varscan2
- HDX | c.620T>A p.M207K | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV99946927; called by muse, mutect2, varscan2
- IP6K2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100151774; called by muse, mutect2
- ITGA7 | c.3072G>C p.W1024C (on ENST00000555728; = p.W980C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99144887; called by muse, mutect2, varscan2
- IWS1 | c.567A>T p.E189D | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99767099; called by muse, mutect2, varscan2
- KIF14 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759631922, COSV66261625; called by muse, mutect2, varscan2
- KRT25 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM166078, COSV56445024; called by muse, mutect2, varscan2
- KSR2 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1265462793, CM1311371, COSV100194485; called by muse, mutect2, varscan2
- LAMA1 | c.5840G>A p.R1947H | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs569445597, COSV67534486; called by muse, mutect2, varscan2
- MAP3K21 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149965923; called by muse, mutect2, varscan2
- MCOLN3 | c.1599C>A p.N533K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100352644; called by muse, mutect2, varscan2
- MGAT4C | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs375819261; called by muse, mutect2, varscan2
- MMP12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs202044860, COSV100404773; called by muse, mutect2, varscan2
- NAV1 | c.4135G>A p.A1379T | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99818496; called by muse, mutect2
- NAV2 | c.971C>T p.P324L (on ENST00000396087 / NM_001244963.2; = p.P301L on NM_145117.5) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100585198; called by muse, mutect2, varscan2
- NCOA6 | c.5960C>T p.P1987L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV100749939; called by muse, mutect2, varscan2
- NYAP2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349573850, COSV55998979; called by muse, mutect2, varscan2
- OR2T12 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1402737053, COSV58776219; called by muse, mutect2, varscan2
- OR4P4 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs771370241, COSV100111638; called by muse, varscan2
- PIKFYVE | c.4257-1G>T p.X1419_splice | Splice Site (SNP) | VAF 7/119 reads (6%) | catalogued as COSV100010141; called by muse, mutect2
- POGK | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs770055510, COSV63311686; called by muse, mutect2, varscan2
- RARG | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV99913981; called by muse, mutect2, varscan2
- RHBDF1 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV99244400; called by muse, mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- RYR2 | c.6576G>A p.M2192I | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV100768956, COSV63689790; called by muse, mutect2, varscan2
- SCN9A | c.3229C>T p.Q1077* (on ENST00000303354; = p.Q1066* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 7/174 reads (4%) | catalogued as rs1553486633, COSV100312032, COSV100313722; called by muse, mutect2
- SEMA3E | c.1701T>A p.N567K | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100317887, COSV57094124; called by muse, mutect2, varscan2
- SLC11A1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as rs770894617, COSV99261980; called by muse, mutect2, varscan2
- SLC34A1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183846; called by muse, mutect2, varscan2
- SLC7A3 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99979450; called by muse, mutect2, varscan2
- STAG2 | c.1719G>C p.Q573H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV99492725; called by muse, mutect2, varscan2
- STIM1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100330594, COSV56158217; called by muse, mutect2, varscan2
- TBC1D9B | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100783461; called by muse, mutect2, varscan2
- TDRD6 | c.4001T>C p.L1334P | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100287355; called by muse, mutect2, varscan2
- THBS1 | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.138); catalogued as COSV99527734; called by muse, mutect2
- TLN2 | c.6858G>T p.Q2286H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.59); catalogued as COSV60893964; called by muse, mutect2, varscan2
- TRDN | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as rs1201954479, COSV100521325; called by muse, mutect2, varscan2
- UHRF1 | c.655G>A p.V219M (on ENST00000612630 / NM_001290050.1; = p.V232M on NM_013282.4) | Missense Mutation (SNP) | VAF 71/528 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs963145028, COSV99503373; called by muse, mutect2, varscan2
- WLS | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1159698998, COSV99259091; called by muse, mutect2
- ZAN | c.3407C>A p.T1136N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs1402162887, COSV100769437; called by muse, mutect2, varscan2
- ZFP90 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 42/218 reads (19%) | catalogued as COSV101238734; called by muse, mutect2, varscan2
- ZIM2 | c.722G>T p.R241I | Missense Mutation (SNP) | VAF 26/694 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.308); catalogued as COSV55646758; called by muse, mutect2
- ZNF507 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV100321682; called by muse, mutect2
- ZNF611 | c.2025G>C p.E675D | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as COSV100160147, COSV100160627; called by muse, mutect2, varscan2
- CCDC93 | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- CLEC17A | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- FRRS1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, varscan2
- AIMP1 | c.114G>A p.L38= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV63638160; called by muse, mutect2
- AL645922.1 | c.3288C>A p.P1096= | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as COSV100963804; called by muse, mutect2
- ATP8A1 | c.516G>T p.L172= | Silent (SNP) | VAF 15/251 reads (6%) | catalogued as COSV100045496; called by muse, mutect2
- BICD1 | c.1947G>A p.L649= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as rs200712359, COSV99862012; called by muse, mutect2, varscan2
- CCP110 | c.840G>A p.L280= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV101195241; called by muse, mutect2
- CRMP1 | c.1143C>T p.V381= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs746043227, COSV100271594; called by muse, mutect2, varscan2
- CYFIP2 | c.2562C>T p.H854= (on ENST00000616178 / NM_001291722.2; = p.H829= on NM_014376.4) | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV100400379; called by muse, mutect2
- EIF3E | c.642C>T p.L214= | Silent (SNP) | VAF 39/286 reads (14%) | catalogued as rs1306229720, COSV99622948; called by muse, mutect2, varscan2
- FAM170A | c.846G>A p.E282= | Silent (SNP) | VAF 108/390 reads (28%) | catalogued as rs1382949376, COSV100088867; called by muse, varscan2
- FAM89A | c.363C>T p.Y121= | Silent (SNP) | VAF 16/281 reads (6%) | catalogued as COSV100792579; called by muse, mutect2
- FIGN | c.2103G>A p.V701= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100291994; called by muse, mutect2, varscan2
- FRAS1 | c.1476C>T p.H492= | Silent (SNP) | VAF 123/168 reads (73%) | catalogued as rs373093881; called by muse, mutect2, varscan2
- GRM4 | c.1839C>T p.N613= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs137929521; called by muse, mutect2, varscan2
- ITGAM | c.1533C>T p.Y511= (on ENST00000648685 / NM_001145808.2; = p.Y510= on NM_000632.4) | Silent (SNP) | VAF 112/253 reads (44%) | catalogued as rs774961999, COSV54935655, COSV99792032; called by muse, mutect2, varscan2
- ITPR1 | c.5310C>T p.P1770= (on ENST00000354582; = p.P1715= on NM_002222.7) | Silent (SNP) | VAF 188/420 reads (45%) | catalogued as rs760202989, COSV100230415; called by muse, mutect2, varscan2
- MMP27 | c.567G>A p.L189= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as rs781688352, COSV99498328; called by muse, mutect2
- MYRF | c.3351C>T p.T1117= (on ENST00000278836 / NM_001127392.3; = p.T1077= on NM_013279.4) | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99606747; called by muse, mutect2, varscan2
- NPHS1 | c.2784G>A p.S928= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs200265333, COSV62288013; called by muse, mutect2, varscan2
- PRADC1 | c.102G>A p.V34= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99240164; called by muse, mutect2, varscan2
- SERPINA4 | c.258C>T p.Y86= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs199872967, COSV100097052, COSV100097100; called by muse, mutect2, varscan2
- TAS2R39 | c.921C>T p.H307= | Silent (SNP) | VAF 102/221 reads (46%) | catalogued as COSV101489401; called by muse, mutect2, varscan2
- TMC2 | c.2127G>A p.P709= | Silent (SNP) | VAF 148/259 reads (57%) | catalogued as rs757980966, COSV62649632; called by muse, mutect2, varscan2
- TOX3 | c.1611C>T p.A537= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99567246; called by muse, mutect2, varscan2
- TTN | c.69549T>C p.D23183= (on ENST00000591111; = p.D15759= on NM_003319.4) | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs1299684694, COSV100601539; called by muse, mutect2, varscan2
- ZSWIM5 | c.2577C>T p.S859= | Silent (SNP) | VAF 46/1042 reads (4%) | catalogued as COSV100655449; called by muse, mutect2
